TCGA case TCGA-29-1694 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1db60f09-7f5a-4f21-8003-06a6abc781db

Demographics
Sex at birth: female; Race: white; Age at index: 45 years; Vital status: Dead; Days to death: 1,187 days (3.2 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 45.2 years (16,523 days); Year of diagnosis: 2002; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: GX; Prior treatment: No.
   Pathology details: Residual tumor measurement: 11-20 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 43 days; Days to treatment end: 161 days; Treatment dose: 4 AUC; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 43 days; Days to treatment end: 161 days; Treatment dose: 150 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, Radioisotope; Initial disease status: Progressive Disease; Days to treatment start: 202 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Progressive Disease; Days to treatment start: 241 days; Days to treatment end: 485 days (1.3 years); Number of cycles: 6; Treatment dose: 50 mg/m2; Route of administration: Intraperitoneal.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Initial disease status: Progressive Disease; Days to treatment start: 339 days; Days to treatment end: 658 days (1.8 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel Poliglumex; Initial disease status: Progressive Disease; Days to treatment start: 658 days (1.8 years); Days to treatment end: 719 days (2.0 years); Number of cycles: 4; Treatment dose: 243 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 750 days (2.1 years); Days to treatment end: 928 days (2.5 years); Number of cycles: 6; Treatment dose: 56 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 969 days (2.7 years); Days to treatment end: 1,071 days (2.9 years); Treatment dose: 1,020 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Progressive Disease; Days to treatment start: 1,057 days (2.9 years); Days to treatment end: 1,071 days (2.9 years); Number of cycles: 2; Treatment dose: 40 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 1,101 days (3.0 years); Days to treatment end: 1,108 days (3.0 years); Number of cycles: 1; Treatment dose: 4 mg; Route of administration: Intravenous.
2. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; Tumor of origin: diagnosis 1 of this record; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 206 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 1,187 days (3.2 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Evidence of recurrence type: Physical Examination; Timepoint: Post Initial Treatment.
- ECOG performance status: 1; Timepoint: Other.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-29-1694-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.2; Intermediate dimension: 1; Shortest dimension: 0.3.
  Slide TCGA-29-1694-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20.
  Slide TCGA-29-1694-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15.
- Sample TCGA-29-1694-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3: Pharmaceutical therapy drug name: Doxorubicin HCL Liposomal; Therapy regimen: Progression.
- Drug treatment 5: Pharmaceutical therapy drug name: CT2103 Taxane Analog; Therapy regimen: Progression.
- Drug treatment 8, Route of administrations: Route of administration: IP.
- Radiation treatment: Therapy regimen: Progression; Therapy regimen other: one time intraperitoneal.
- Follow-up form: Treatment outcome first course: Stable Disease; Tumor status: With tumor.
- Follow-up form, New tumor event: New tumor event type: Locoregional Disease; New tumor event diagnosis evidence: First Seen At Further Surgery; New tumor event surgery: Yes; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,187 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,187 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,187 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-29-1694-01A-01D-0559-01): tumor purity 0.79, ploidy 1.83, whole-genome doublings 0.
